Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3DT, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3DT-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. LEFT LEVEL 6 LYMPH NODE (EXCISION):

- METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF ONE (1 OF 1) LYMPH NODE (See Note).

Note: The metastatic carcinoma is best seen on the frozen section (slide 1FS2).

2. THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Left lobe

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE:

2.5 cm

FOCALITY:

Unifocal

LYMPH NODES:

Metastatic carcinoma in 1 of 4 lymph nodes.

EXTENT OF INVASION (7th Edition AJCC):

PRIMARY TUMOR:

pT2: Tumor >2 cm but <4 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: <1 mm (anterior margin)

VENOUS/LYMPHATIC INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Thyroiditis

NOTE: Three parathyroid glands are identified.

HIFAA Discrepancy		☒
		10/21/11

1CD-0-3
carcinoma, papillary, thyroid, 8260/3
Site: thyroid, NOS C73.9
10/21/11

Source: NCI Genomic Data Commons file 9f3714b0-7cc5-4dcd-aa3b-c9b38e6320ce (TCGA-ET-A3DT.18B667CB-A763-4EF9-8498-6AD7ADD697BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).